Somatic mutation profile of tumor specimen MP2PRT-PAPGZN-TMP1-A (aliquot MP2PRT-PAPGZN-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPGZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,609 days).
Specimen MP2PRT-PAPGZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9f5e350-0465-475f-902c-c8a02bd9e920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGZN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGZN-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/865844e8-3b8a-4c27-905b-289113ef6cf8

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, In Frame Del 3, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.4126C>T p.Q1376* | Nonsense Mutation (SNP) | VAF 117/368 reads (32%) | catalogued as COSV66348663; called by muse, mutect2, varscan2
- LONRF1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as rs770316883, COSV68037516; called by muse, varscan2
- NLRP9 | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 190/441 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs376455768; called by muse, varscan2
- SLITRK4 | c.2035G>C p.D679H | Missense Mutation (SNP) | VAF 221/457 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV100567071; called by muse, mutect2, varscan2
- APBA1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 167/585 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATXN1 | c.295_345del p.A99_V115del | In Frame Del (DEL) | VAF 3/31 reads (10%) | called by mutect2*, pindel
- BCOR | c.2556C>A p.F852L | Missense Mutation (SNP) | VAF 261/593 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRB3 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 158/393 reads (40%) | called by muse, varscan2
- GNAL | c.541G>C p.D181H (on ENST00000269162 / NM_001142339.3; = p.D258H on NM_182978.4) | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, varscan2
- HOXB6 | c.115T>G p.Y39D | Missense Mutation (SNP) | VAF 267/595 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- NRG4 | c.327_328insAGAA p.H110Rfs*5 | Frame Shift Ins (INS) | VAF 42/113 reads (37%) | called by mutect2, varscan2
- OLFML1 | c.986_1036del p.V329_Y345del | In Frame Del (DEL) | VAF 4/41 reads (10%) | called by mutect2*, pindel
- PRKAR1B | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SDK2 | c.4008_4009insGGCCC p.T1337Gfs*58 | Frame Shift Ins (INS) | VAF 54/131 reads (41%) | called by pindel, varscan2
- TPO | c.1191_1236del p.E399Tfs*37 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2*, pindel
- TTN | c.99813_99863del p.S33272_E33288del (on ENST00000591111; = p.S25848_E25864del on NM_003319.4) | In Frame Del (DEL) | VAF 3/29 reads (10%) | called by mutect2*, pindel
- ZFP69 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, varscan2
- ZFP69 | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTS17 | c.2664C>T p.C888= | Silent (SNP) | VAF 306/628 reads (49%) | catalogued as rs1241458658; called by muse, varscan2
- OXR1 | c.804G>A p.V268= (on ENST00000442977 / NM_001198532.1; = p.V267= on NM_018002.3) | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- UBE4A | c.324C>T p.G108= | Silent (SNP) | VAF 92/215 reads (43%) | called by muse, mutect2, varscan2
- UGT2B4 | c.618T>A p.T206= | Silent (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
